Gene-level copy-number profile of tumor specimen TCGA-39-5036-01A from TCGA case TCGA-39-5036, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.8 years (26,963 days).
Specimen TCGA-39-5036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5dad44df-c11c-4098-87bd-41e1c77b9e22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5036-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d1cd2afc-2da1-4364-a402-dcfa7954e2fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 15,570; copy number 3: 28,813; copy number 4: 9,096; copy number 5: 4,343; copy number 6: 752; copy number 7: 214; copy number 8: 343; copy number 9: 276; copy number 10: 221; copy number 11: 125; copy number 12: 38; copy number 13: 18; copy number 19: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5036-01A-01D-1439-01): tumor purity 0.64, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,238 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:193,170,704–202,769,757, 182 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr3:162,486,541–187,207,629, 406 genes, copy number 8–9 (broad region; genes not listed).
- chr3:189,631,389–198,222,513, 213 genes, copy number 8 (broad region; genes not listed).
- chr4:60,750,575–74,388,749, 216 genes, copy number 7–19 (broad region; genes not listed).
- chr22:19,875,517–19,941,820, 1 gene, copy number 10 (within-gene range 5–10): TXNRD2.
- chr22:19,941,371–22,721,145, 220 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
